Somatic mutation profile of tumor specimen HCM-BROD-0008-C25-06A (aliquot HCM-BROD-0008-C25-06A-01D-A78W-36) from HCMI case HCM-BROD-0008-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 63.5 years (23,186 days).
Specimen HCM-BROD-0008-C25-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01ab589b-5c33-4ed1-8f4c-225a9ba3dfe1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0008-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0008-C25-10A-01D-A78W-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/186b7d90-af18-4a85-b646-f828845f03ab

The open-access MAF lists 152 somatic variants for this specimen: 108 protein-altering or splice-affecting, 28 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 28, Nonsense Mutation 9, Intron 7, Frame Shift Del 4, Frame Shift Ins 3, Splice Site 3, RNA 2, 3'Flank 2, 5'UTR 2, 3'UTR 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 206/485 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NBN | c.1747C>T p.Q583* | Nonsense Mutation (SNP) | VAF 12/102 reads (12%) | catalogued as rs864622143; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- TP53 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 324/645 reads (50%) | hotspot (GDC flag); catalogued as COSV52666332, COSV52700326, COSV52746468; called by muse, mutect2, varscan2
- ARL8B | c.290A>T p.D97V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56579322; called by muse, mutect2, varscan2
- B3GALT2 | c.83T>C p.I28T | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs555499650; called by muse, mutect2, varscan2
- BICC1 | c.2516G>A p.R839H | Missense Mutation (SNP) | VAF 69/413 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs200282277; called by muse, mutect2, varscan2
- BLOC1S5 | c.71A>C p.D24A | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1561874721; called by muse, mutect2
- C1orf56 | c.317C>A p.S106Y | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV54848196; called by muse, mutect2
- CYP2D7 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.529); catalogued as rs1282242124; called by muse, mutect2
- DNAH6 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs372068392, COSV52882193; called by muse, mutect2
- ELP1 | c.3593G>A p.R1198Q | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200322331; called by muse, mutect2
- FANCM | c.5538A>C p.E1846D | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1416312500, COSV57498795; called by muse, mutect2
- FLAD1 | c.218dup p.C74Vfs*28 | Frame Shift Ins (INS) | VAF 17/79 reads (22%) | catalogued as rs772370005; called by mutect2, pindel, varscan2
- GOLGA6L22 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 120/479 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.225); catalogued as rs1459454497; called by mutect2, varscan2
- GTF2IRD2 | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 32/742 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782290129, COSV63100333; called by muse, mutect2
- LAMC3 | c.2816G>T p.R939L | Missense Mutation (SNP) | VAF 48/282 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs777019483; called by muse, mutect2, varscan2
- LMNTD1 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 14/371 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51447606; called by muse, mutect2
- LRP1B | c.11954G>A p.W3985* | Nonsense Mutation (SNP) | VAF 73/475 reads (15%) | catalogued as COSV67232700, COSV67256675; called by muse, mutect2, varscan2
- MRC2 | c.3427C>G p.P1143A | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); catalogued as COSV57637963; called by muse, mutect2
- MTSS1 | c.2004A>C p.Q668H | Missense Mutation (SNP) | VAF 30/604 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1474965023; called by muse, mutect2
- NEB | c.13439T>C p.I4480T | Missense Mutation (SNP) | VAF 94/385 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs764500250; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NTSR1 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as rs754914970; called by muse, mutect2, varscan2
- OR10J1 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 72/368 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV71129224; called by muse, mutect2, varscan2
- PCSK2 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 40/389 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.046); catalogued as rs775656155, COSV52729436, COSV52732713; called by muse, mutect2, varscan2
- PLEC | c.8925G>C p.E2975D (on ENST00000322810 / NM_201380.4; = p.E2865D on NM_000445.5) | Missense Mutation (SNP) | VAF 29/667 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV59664173; called by muse, mutect2
- PTPRG | c.1552G>A p.G518S | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs764776482, COSV55640529; called by muse, mutect2, varscan2
- RAE1 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64798027; called by muse, mutect2, varscan2
- SLC5A5 | c.1842C>G p.F614L | Missense Mutation (SNP) | VAF 26/514 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs752445428, COSV55831920; called by muse, mutect2
- SPATA31E1 | c.1354G>C p.A452P | Missense Mutation (SNP) | VAF 18/388 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV100350352; called by muse, mutect2
- STAB1 | c.3862C>T p.Q1288* | Nonsense Mutation (SNP) | VAF 18/129 reads (14%) | catalogued as rs1206217550; called by muse, mutect2, varscan2
- TAS1R3 | c.1957del p.L653Cfs*14 | Frame Shift Del (DEL) | VAF 67/305 reads (22%) | catalogued as COSV104411930; called by mutect2, pindel, varscan2
- TAT | c.202A>C p.N68H | Missense Mutation (SNP) | VAF 37/311 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.113); catalogued as rs763274703; called by muse, mutect2, varscan2
- TTLL7 | c.2044A>C p.S682R | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99553110; called by muse, mutect2
- TTN | c.43240C>T p.R14414C (on ENST00000591111; = p.R6990C on NM_003319.4) | Missense Mutation (SNP) | VAF 19/233 reads (8%) | PolyPhen benign (0.001); catalogued as rs1012450335, COSV59880703; called by muse, mutect2
- TUBA3C | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.085); catalogued as rs139914455, COSV67139666; called by muse, mutect2, varscan2
- ZC3H4 | c.2639C>T p.S880F | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs1568527692; called by muse, mutect2
- ACAN | c.5824G>C p.V1942L | Missense Mutation (SNP) | VAF 31/546 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); called by muse, mutect2
- ADAM7 | c.2209-2A>G p.X737_splice | Splice Site (SNP) | VAF 58/116 reads (50%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.2698C>T p.P900S | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.349); called by muse, mutect2
- ADCY1 | c.3052A>C p.I1018L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- AKR1C1 | c.482A>C p.K161T | Missense Mutation (SNP) | VAF 29/423 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- ALG13 | c.1006-1G>T p.X336_splice | Splice Site (SNP) | VAF 18/108 reads (17%) | called by mutect2, varscan2
- ARMCX5 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 63/209 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ATP2B3 | c.2930T>C p.V977A | Missense Mutation (SNP) | VAF 64/1072 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- BRD1 | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 143/462 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CEP152 | c.4567A>C p.T1523P (on ENST00000380950 / NM_001194998.2; = p.T1467P on NM_014985.4) | Missense Mutation (SNP) | VAF 18/333 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- CEP57 | c.128A>C p.K43T | Missense Mutation (SNP) | VAF 21/323 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- CFAP46 | c.2924+4A>C | Splice Region (SNP) | VAF 18/358 reads (5%) | called by muse, mutect2
- CFAP97 | c.824A>T p.N275I | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2
- CHD9 | c.3653T>G p.L1218R | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CLSTN3 | c.51_64+7del p.X17_splice | Splice Site (DEL) | VAF 95/312 reads (30%) | called by mutect2, pindel, varscan2
- CNGA2 | c.1453G>C p.G485R | Missense Mutation (SNP) | VAF 56/337 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTN3 | c.850A>C p.I284L | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2
- COL18A1 | c.4395G>C p.W1465C (on ENST00000359759 / NM_130444.3; = p.W1230C on NM_030582.4) | Missense Mutation (SNP) | VAF 40/542 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2
- CYLC2 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- DDHD2 | c.1932A>C p.E644D | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DIAPH2 | c.557T>A p.L186H | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DLD | c.959A>C p.K320T | Missense Mutation (SNP) | VAF 23/277 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2
- DNAH9 | c.4702A>G p.N1568D | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.33); called by muse, mutect2
- DOCK2 | c.2225A>G p.Y742C | Missense Mutation (SNP) | VAF 13/197 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- EFHC2 | c.775A>T p.T259S | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- EPHX1 | c.115A>T p.R39W | Missense Mutation (SNP) | VAF 13/272 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- FBXW11 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLG | c.7556A>C p.N2519T | Missense Mutation (SNP) | VAF 49/789 reads (6%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- FOXC2 | c.338A>C p.K113T | Missense Mutation (SNP) | VAF 54/787 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- HECW1 | c.4013T>G p.L1338R | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.436); called by muse, mutect2
- HMX3 | c.570A>C p.E190D | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- IGSF22 | c.2543A>C p.K848T (on ENST00000319338; = p.K949T on NM_173588.4) | Missense Mutation (SNP) | VAF 46/704 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.326); called by muse, mutect2
- IGSF23 | c.519G>C p.M173I | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2
- IRS4 | c.2375dup p.N792Kfs*33 | Frame Shift Ins (INS) | VAF 271/871 reads (31%) | called by mutect2, pindel, varscan2
- ITPR2 | c.568G>T p.G190W | Missense Mutation (SNP) | VAF 16/369 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LSM11 | c.1052A>T p.E351V | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- MCF2 | c.2206dup p.C736Lfs*6 | Frame Shift Ins (INS) | VAF 86/531 reads (16%) | called by mutect2, pindel, varscan2
- MCM5 | c.642_644del p.I214del | In Frame Del (DEL) | VAF 80/290 reads (28%) | called by pindel, varscan2
- MET | c.2849G>T p.G950V | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.066); called by muse, mutect2
- MRC2 | c.2905C>A p.L969M | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- MTMR14 | c.1501T>G p.L501V | Missense Mutation (SNP) | VAF 13/286 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- MUC16 | c.39941G>T p.G13314V | Missense Mutation (SNP) | VAF 19/321 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2
- MYLK | c.4242G>T p.E1414D | Missense Mutation (SNP) | VAF 90/503 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- MYO18B | c.915A>T p.E305D | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.085); called by muse, mutect2
- OR4K15 | c.311A>C p.K104T (on ENST00000305051; = p.K80T on NM_001005486.1) | Missense Mutation (SNP) | VAF 35/453 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- PCDHB2 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 14/253 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PHACTR1 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PPFIBP1 | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 100/697 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRDM13 | c.2113C>T p.R705C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); called by muse, mutect2
- PRDM14 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- PROM2 | c.490T>G p.L164V | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- PTGER2 | c.1035del p.C346Vfs*31 | Frame Shift Del (DEL) | VAF 21/196 reads (11%) | called by mutect2, pindel, varscan2
- PTGFR | c.107T>C p.F36S | Missense Mutation (SNP) | VAF 20/289 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.026); called by muse, mutect2
- QRICH2 | c.2015A>C p.Q672P | Missense Mutation (SNP) | VAF 63/1331 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); called by muse, mutect2
- QRICH2 | c.2014C>T p.Q672* | Nonsense Mutation (SNP) | VAF 61/1338 reads (5%) | called by muse, mutect2
- RELN | c.7576C>G p.P2526A | Missense Mutation (SNP) | VAF 26/802 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2
- ROR2 | c.2501T>G p.L834R | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- RTF2 | c.398G>T p.R133M | Missense Mutation (SNP) | VAF 15/354 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RYR2 | c.8004C>A p.C2668* | Nonsense Mutation (SNP) | VAF 24/424 reads (6%) | called by muse, mutect2
- RYR3 | c.4006G>A p.A1336T | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- SLC12A5 | c.2402A>T p.N801I (on ENST00000454036 / NM_001134771.2; = p.N778I on NM_020708.5) | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2
- SLC35F4 | c.58G>C p.A20P | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2
- STT3B | c.1253del p.L418Hfs*39 | Frame Shift Del (DEL) | VAF 33/111 reads (30%) | called by mutect2, pindel, varscan2
- TECR | c.587_588del p.L196Rfs*119 | Frame Shift Del (DEL) | VAF 226/928 reads (24%) | called by mutect2, pindel, varscan2
- TEX13C | c.2452A>T p.K818* | Nonsense Mutation (SNP) | VAF 230/679 reads (34%) | called by muse, mutect2, varscan2
- THNSL1 | c.931G>T p.G311* | Nonsense Mutation (SNP) | VAF 164/404 reads (41%) | called by muse, mutect2, varscan2
- TOPBP1 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 126/290 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- TRIM56 | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TTN | c.95925G>C p.K31975N (on ENST00000591111; = p.K24551N on NM_003319.4) | Missense Mutation (SNP) | VAF 14/110 reads (13%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TUBG1 | c.359A>G p.D120G | Missense Mutation (SNP) | VAF 13/420 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- UBR5 | c.4169A>T p.K1390M | Missense Mutation (SNP) | VAF 40/403 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- UBR5 | c.4168A>T p.K1390* | Nonsense Mutation (SNP) | VAF 40/406 reads (10%) | called by muse, mutect2
- ASTN2 | c.684C>T p.Y228= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs753397797, COSV57754418; called by muse, mutect2, varscan2
- CFAP251 | c.3066C>T p.I1022= | Silent (SNP) | VAF 70/378 reads (19%) | catalogued as rs187982927; called by muse, mutect2, varscan2
- CNTNAP4 | c.1938T>C p.N646= | Silent (SNP) | VAF 44/131 reads (34%) | catalogued as COSV56670463; called by muse, mutect2, varscan2
- CTDSPL | c.264A>G p.P88= | Silent (SNP) | VAF 11/236 reads (5%) | called by muse, mutect2
- DCBLD2 | c.939G>A p.V313= | Silent (SNP) | VAF 69/878 reads (8%) | called by muse, mutect2
- DKK2 | c.448C>A p.R150= | Silent (SNP) | VAF 94/205 reads (46%) | catalogued as rs1254069801, COSV53397188, COSV53400080; called by muse, mutect2, varscan2
- DMWD | c.1035C>T p.G345= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as rs142998214; called by muse, mutect2, varscan2
- DMXL1 | c.4686T>G p.A1562= | Silent (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- FLT4 | c.2553C>T p.L851= | Silent (SNP) | VAF 53/102 reads (52%) | catalogued as rs756742987; called by muse, mutect2, varscan2
- MARCHF6 | c.2502A>G p.L834= | Silent (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2
- NELFB | c.579G>C p.V193= | Silent (SNP) | VAF 28/610 reads (5%) | catalogued as COSV58024953; called by muse, mutect2
- NOL8 | c.1350C>T p.P450= | Silent (SNP) | VAF 54/271 reads (20%) | catalogued as rs1461897210; called by muse, mutect2, varscan2
- PCBP4 | c.894C>T p.I298= (on ENST00000322099 / NM_033010.2; = p.I255= on NM_020418.4) | Silent (SNP) | VAF 63/144 reads (44%) | catalogued as rs199654401; called by muse, mutect2, varscan2
- PCDHA8 | c.1914C>T p.D638= | Silent (SNP) | VAF 46/386 reads (12%) | catalogued as rs782176303, COSV65332432; called by muse, mutect2, varscan2
- PCDHGA2 | c.1965C>T p.S655= | Silent (SNP) | VAF 112/534 reads (21%) | catalogued as rs771072942, COSV99541905; called by muse, mutect2, varscan2
- PRUNE2 | c.2298T>G p.A766= | Silent (SNP) | VAF 22/386 reads (6%) | called by muse, mutect2
- RASAL3 | c.1527C>T p.I509= | Silent (SNP) | VAF 58/448 reads (13%) | catalogued as rs1316912232; called by muse, mutect2, varscan2
- SLX1A | c.717G>A p.E239= | Silent (SNP) | VAF 34/144 reads (24%) | called by mutect2, varscan2
- SPATA20 | c.1453C>T p.L485= (on ENST00000356488 / NM_001258372.1; = p.L501= on NM_022827.4) | Silent (SNP) | VAF 12/358 reads (3%) | called by muse, mutect2
- TAF1A | c.387C>T p.G129= | Silent (SNP) | VAF 27/175 reads (15%) | catalogued as rs1438915794, COSV61919983; called by muse, mutect2, varscan2
- TAF5L | c.96A>T p.G32= | Silent (SNP) | VAF 32/498 reads (6%) | called by muse, mutect2
- TAF7L | c.138C>T p.S46= | Silent (SNP) | VAF 415/1038 reads (40%) | called by muse, mutect2, varscan2
- USP13 | c.969G>T p.S323= | Silent (SNP) | VAF 18/396 reads (5%) | catalogued as COSV99831071, COSV99831916; called by muse, mutect2
- ZBTB40 | c.1191C>G p.G397= | Silent (SNP) | VAF 50/589 reads (8%) | called by muse, mutect2
- ZDBF2 | c.1432A>C p.R478= | Silent (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- ZFHX4 | c.7164C>T p.S2388= | Silent (SNP) | VAF 29/284 reads (10%) | called by muse, mutect2
- ZIM2 | c.837G>A p.P279= | Silent (SNP) | VAF 37/239 reads (15%) | catalogued as rs191866455, COSV55639172; called by muse, mutect2, varscan2
- ZNF517 | c.600C>T p.T200= | Silent (SNP) | VAF 46/417 reads (11%) | catalogued as rs535413984; called by muse, mutect2, varscan2
- ARSB | c.1213+23258G>A | Intron (SNP) | VAF 100/406 reads (25%) | catalogued as rs995643493; called by muse, mutect2, varscan2
- BRCA1 | c.-61C>G | 5'UTR (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- CALY | c.246+91G>A | Intron (SNP) | VAF 38/144 reads (26%) | called by muse, mutect2, varscan2
- CC2D2B | chr10:96032707 del AAAAGTTTGCACTTTGGATGCTACTGACATG | 3'Flank (DEL) | VAF 37/106 reads (35%) | called by mutect2, pindel
- CPS1 | c.3667-20G>A | Intron (SNP) | VAF 34/378 reads (9%) | catalogued as rs369845787; called by muse, mutect2
- CRIP1 | c.40+25C>G | Intron (SNP) | VAF 25/196 reads (13%) | called by muse, mutect2, varscan2
- DPP10 | c.61-147015C>T | Intron (SNP) | VAF 64/222 reads (29%) | catalogued as rs756659116; called by muse, mutect2, varscan2
- KDM5B | c.711+462G>T | Intron (SNP) | VAF 7/86 reads (8%) | catalogued as rs1170770787; called by muse, mutect2
- NPY2R | c.-18A>C | 5'UTR (SNP) | VAF 33/398 reads (8%) | called by muse, mutect2
- NYNRIN | c.*785C>G | 3'UTR (SNP) | VAF 24/197 reads (12%) | called by muse, mutect2, varscan2
- PDIA3P1 | n.1541T>G | RNA (SNP) | VAF 15/399 reads (4%) | called by muse, mutect2
- PHYHIP | c.165+522G>A | Intron (SNP) | VAF 20/210 reads (10%) | called by muse, mutect2
- SHROOM4 | c.*420G>A | 3'UTR (SNP) | VAF 40/289 reads (14%) | called by muse, mutect2, varscan2
- SSPOP | n.9927T>A | RNA (SNP) | VAF 24/305 reads (8%) | called by muse, mutect2
- SYT14 | chr1:210163234 C>G | 3'Flank (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2, varscan2
- Unknown | chr17:43379201 C>T | IGR (SNP) | VAF 85/243 reads (35%) | called by muse, mutect2, varscan2
